Surgical pathology report (de-identified scan), TCGA case TCGA-UP-A6WW, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site  Boston Medical Center, specimen TCGA-UP-A6WW-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

Date Taken:

Client:

Date Received:

DOB: (Age) Sex (Age:) M

Date Reported:

SPECIMEN(S) RECEIVED

- A: RIGHT TONSIL ANTERIOR MARGIN
- B: RIGHT TONSIL SUPERIOR MARGIN
- C: RIGHT TONSIL POSTERIOR MARGIN
- D: RIGHT TONSIL INFERIOR MARGIN
- E: RIGHT TONSIL DEEP MARGIN
- F: MEDIAL TONGUE MARGIN
- G: RIGHT LEVEL I
- H: RIGHT LEVEL II AND III
- I: RIGHT LEVEL IV
- J: RIGHT LEVEL V
- K: RIGHT BASE OF TONGUE AND PHARYNX
- L: LEFT LEVEL II
- M: LEFT LEVEL III

ICD-O-3
Carcinoma, squamous cell NOS
8070/3
Site CECF
Tongue NOS C62.9
path
Ventral surface of tongue NOS
C02.2
JW 8/11/13

FINAL DIAGNOSIS

A. RIGHT TONSIL ANTERIOR MARGIN:

SKIN, FIBROCONNECTIVE TISSUE AND SKELETAL MUSCLE.
NO TUMOR IDENTIFIED.

B. RIGHT TONSIL SUPERIOR MARGIN:

FIBROADIPOSE TISSUE.
NO TUMOR IDENTIFIED.

C. RIGHT TONSIL POSTERIOR MARGIN:

SKIN, FIBROCONNECTIVE TISSUE AND SKELETAL MUSCLE.
NO TUMOR IDENTIFIED.

D. RIGHT TONSIL INFERIOR MARGIN:

SKIN, FIBROADIPOSE TISSUE AND SKELETAL MUSCLE WITH CHRONIC INFLAMMATION.
NO TUMOR IDENTIFIED.

E. RIGHT TONSIL DEEP MARGIN:

SKELETAL MUSCLE.
NO TUMOR IDENTIFIED.

F. MEDIAL TONGUE MARGIN:

SKIN, FIBROADIPOSE TISSUE AND SKELETAL MUSCLE WITH CHRONIC INFLAMMATION.
NO TUMOR IDENTIFIED.

G. RIGHT LEVEL I:

FIVE (5) OF SEVEN (7) LYMPH NODES POSITIVE FOR METASTATIC SQUAMOUS CELL CARCINOMA.
SALIVARY GLAND.

H. RIGHT LEVEL II AND III:

FOUR (4) OF SIXTEEN (16) LYMPH NODES POSITIVE FOR METASTATIC SQUAMOUS CELL CARCINOMA.

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

**SQUAMOUS CELL CARCINOMA INVOLVING SALIVARY GLAND AND SKELETAL MUSCLE.
LYMPHOVASCULAR SPACE AND PERINEURAL INVASION IDENTIFIED.**

I. RIGHT LEVEL IV:

TWO (2) OF EIGHTEEN (18) LYMPH NODES POSITIVE FOR METASTATIC SQUAMOUS CELL CARCINOMA.

J. RIGHT LEVEL V:

**SIX (6) REACTIVE LYMPH NODES.
NO TUMOR IDENTIFIED.**

K. RIGHT BASE OF TONGUE AND PHARYNX:

SYNOPTIC REPORT:

LIP AND ORAL CAVITY: Resection

Specimen:

Ventral surface of tongue, not otherwise specified (NOS)
Other (specify): Pharynx

Received:

Fresh

Procedure:

Resection
Glossectomy (specify): 6.5 x 4.8 x 3.5 cm

Specimen Integrity:

Intact

Specimen Size:

Greatest dimensions: 6.5 x 4.8 x 3.5 cm

Specimen Laterality:

Right

Tumor Site:

Ventral surface of tongue, NOS

Tumor Focality:

Single focus

Tumor Size

Greatest dimension: 3.3 cm
Additional dimensions: 2.8 x 2.1 cm

Tumor Description:

Gross subtype:

Endophytic

Histologic Type:

Squamous cell carcinoma, conventional

Histologic Grade:

G2: Moderately-differentiated

Margins:

Margins uninvolved by invasive carcinoma
Distance from closest margin: 0.2 cm
Specify margin: Posterior

Treatment Effect:

Not identified

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

Lymph-Vascular Invasion:
Present

Perineural Invasion:
Present

Lymph Nodes, Extranodal Extension:
Present

Pathologic Staging (pTNM):

Primary Tumor (pT):
pT2: Tumor more than 2 cm but not more than 4 cm in greatest dimension

Regional Lymph nodes (pN):
pN2c: Metastasis in a single ipsilateral lymph node, more than 3 cm but not more than 6 cm in greatest dimension
Specify: Number examined: 53
Number involved: 14

Distant Metastasis (pM):
Not applicable

AJCC PATHOLOGIC STAGE: (pT2, pN2c).

L. LEFT LEVEL II:
THREE REACTIVE LYMPH NODES.
NO TUMOR IDENTIFIED.

M. LEFT LEVEL III:
METASTATIC SQUAMOUS CELL CARCINOMA PRESENT IN TWO LYMPH NODES.

*** Report Electronically Signed ***

CLINICAL DIAGNOSIS AND HISTORY

Squamous cell carcinoma of the tonsil

FROZEN SECTION DIAGNOSIS

AFS: NO INVASIVE CARCINOMA SEEN.
BFS: NO INVASIVE CARCINOMA SEEN.
CFS: NO INVASIVE CARCINOMA SEEN.
DFS: NO INVASIVE CARCINOMA SEEN.
EFS: NO INVASIVE CARCINOMA SEEN.
FFS: NO INVASIVE CARCINOMA SEEN.

Dr. notified on

GROSS DESCRIPTION

The specimen is received fresh in thirteen containers labeled with the patient's name, medical record number, and identified as A.

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

"Right Tonsil Anterior Margin", B. "Right Tonsil Superior Margin", C. "Right Tonsil Posterior Margin", D. "Right Tonsil Inferior Margin", E. "Right Tonsil Deep Margin", F. "Medial Tongue Margin", G. "Right Level I", H. "Right Level II and 3 ", I. "Right Level IV", J. "Right Level V", K. "Right Basal of tongue and Pharynx ", L. "Left Level II " and M. "Left Level III

Specimen A consists of one fragment of soft tissue measuring 1.1 x 0.6 x 0.3 cm. A frozen section has been performed on the specimen and the remaining specimen is submitted entirely in one cassette labeled A.

Specimen B consists of one fragment of soft tissue measuring 0.8 x 0.4 x 0.3 cm. A frozen section has been performed on the specimen and the remaining specimen is submitted entirely in one cassette labeled B.

Specimen C consists of one fragment of soft tissue measuring 0.8 x 0.5 x 0.2 cm. A frozen section has been performed on the specimen and the remaining specimen is submitted entirely in one cassette labeled C.

Specimen D consists of one fragment of soft tissue measuring 0.7 x 0.5 x 0.2 cm. A frozen section has been performed on the specimen and the remaining specimen is submitted entirely in one cassette labeled D.

Specimen E consists of one fragment of soft tissue measuring 1 x 0.8 x 1.5 cm. A frozen section has been performed on the specimen and the remaining specimen is submitted entirely in one cassette labeled E.

Specimen F consists of one fragment of soft tissue measuring 1 x 0.7 x 0.3 cm. A frozen section has been performed on the specimen and the remaining specimen is submitted entirely in one cassette labeled F.

Specimen G consists of one fragment of fibroadipose tissue with multiple lymph nodes and salivary gland measuring 7 x 5 x 2 cm. The specimen is submitted representatively as follows: G1-1.7 cm lymph node, bisected, G2-1.8 cm lymph node, bisected, G3-1.4 cm lymph node, bisected, G4-three lymph nodes, G5 and G6-salivary gland.

Specimen H consists of one fragment of fibroadipose tissue with skeletal muscle and multiple lymph nodes measuring 7 x 6 x 5 cm. The specimen is submitted representatively as follows: H1 and H2 2.5 cm lymph node, bisected, H3-2 cm lymph node, bisected, H4-1.5 cm lymph node, bisected, H5-1.3 cm lymph nodes, bisected, H6-five lymph nodes, H7-1.2 cm lymph node, bisected, H8-five lymph nodes, H9 thru H15-tumor nodules/lymphoid aggregates, submitted representatively.

Specimen I. consists of one fragment of fibroadipose tissue with multiple lymph nodes measuring 7 x 5 x 2.5 cm. The specimen is submitted representatively as follows: I1-six lymph nodes, I2-five lymph nodes, I3-three lymph nodes, I4 thru I10-4 cm lymph nodes.

Specimen J consists of one fragment of fibroadipose tissue with multiple lymph nodes measuring 8 x 6.5 x 1 cm. Multiple lymph nodes are identified measuring 0.7-0.2 cm in diameter and submitted entirely in three cassettes labeled J1 and J3.

Specimen K consists of right base of tongue and pharynx measuring 6.5 cm from anterior to posterior, 4.8 cm from medial to lateral, and 3.5 cm from superior to inferior. The specimen has been oriented by the surgeon with a short stitch indicating the anterior margin, and a long stitch indicating the lateral margin. The specimen is inked as follows: red-superior, black-posterior, blue-inferior, orange-anterior, yellow-medial, green-lateral. The specimen is serially sectioned from posterior to anterior to reveal a whitish-tan, irregular, infiltrating firm nodule measuring 3.3 x 2.8 x 2.1 cm, grossly abutting the lateral, medial, superior, posterior and inferior margins. The specimen is submitted representatively in ten cassettes labeled K1 thru K10.

Specimen L. consists of 4 x 2 x 0.5 cm aggregate of fibrofatty tissue from which 2 whole lymph nodes are dissected which measure 1 cm and 3 cm. The entire specimen is submitted as follows: L1-trisected-smaller lymph node, L2 thru L4-serially sectioned, larger lymph node.

Specimen M. consists of 3.5 x 2 x 1 cm piece of fibroadipose tissue from which 2 whole lymph nodes are dissected which measure 1 cm and 2.5 cm. The larger lymph node is sectioned to reveal a tan-white, necrotic cut surface grossly consistent with a metastatic deposit. The sections are submitted as follows: M1-bisected smaller lymph node, M2-representative section, larger lymph node.

Dictated by:

By the signature above, the senior pathologist certifies that s/he personally conducted the evaluation of the described specimen(s) and rendered the diagnosis(es) related thereto.

Source: NCI Genomic Data Commons file a264d3d2-20e0-4d4e-a443-eb171f37a9bb (TCGA-UP-A6WW.5CFD2D42-23D5-4561-9031-E1F79BC1B29E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).